Somatic mutation profile of tumor specimen TCGA-R5-A805-01A (aliquot TCGA-R5-A805-01A-11D-A364-08) from TCGA case TCGA-R5-A805, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 71.5 years (26,122 days).
Specimen TCGA-R5-A805-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a372a558-86dc-4050-b317-d4f78fd36223.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R5-A805-10A (Blood Derived Normal), aliquot TCGA-R5-A805-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd9f7c1d-401c-47bd-acdf-2ce5d343e2ab

The open-access MAF lists 134 somatic variants for this specimen: 101 protein-altering or splice-affecting, 27 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 27, RNA 3, In Frame Del 1, Splice Site 1, Intron 1, Nonsense Mutation 1, Frame Shift Del 1, Splice Region 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM19 | c.2393T>G p.L798R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99977979; called by muse, mutect2, varscan2
- APBA2 | c.91A>G p.S31G | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV101382454; called by muse, mutect2
- ARHGAP28 | c.734T>G p.L245R (on ENST00000383472 / NM_001366230.1; = p.L86R on NM_001010000.3) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as COSV51637654, COSV99151234; called by mutect2, varscan2
- ARMC9 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as COSV100589917; called by muse, mutect2
- BLOC1S1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV57725374; called by muse, mutect2, varscan2
- BRDT | c.387A>C p.K129N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100746545; called by muse, mutect2, varscan2
- CADPS | c.854A>C p.K285T | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV99340011; called by muse, mutect2, varscan2
- CD163 | c.1519T>C p.F507L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as COSV100776025; called by muse, mutect2, varscan2
- CD1D | c.509A>C p.K170T | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV100939636; called by muse, mutect2, varscan2
- CHD9 | c.4984del p.V1662Yfs*87 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs1179226394; called by mutect2, pindel, varscan2
- CHIT1 | c.484T>G p.L162V | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV99705480; called by muse, mutect2, varscan2
- CHODL | c.345C>G p.C115W | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100166971; called by muse, mutect2, varscan2
- CNTN1 | c.2971A>G p.K991E | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.065); catalogued as COSV100751755; called by muse, mutect2, varscan2
- COL1A2 | c.3402A>T p.E1134D | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV51955221, COSV99800554; called by muse, mutect2, varscan2
- COL24A1 | c.3585A>C p.E1195D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.98); PolyPhen benign (0.035); catalogued as COSV65310975; called by muse, mutect2, varscan2
- CORO1C | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV54594899; called by muse, mutect2, varscan2
- CPE | c.1262T>G p.L421R | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV68581824; called by muse, mutect2, varscan2
- CRB1 | c.1970A>C p.N657T | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV100958023, COSV66330822; called by muse, mutect2, varscan2
- CSMD3 | c.3455A>G p.N1152S (on ENST00000297405 / NM_001363185.1; = p.N1048S on NM_052900.3) | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV99842634; called by muse, mutect2, varscan2
- DNAH9 | c.550A>C p.T184P | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as COSV99307209; called by muse, mutect2, varscan2
- DSEL | c.1980A>C p.E660D | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.994); catalogued as COSV100025936; called by muse, mutect2, varscan2
- EHBP1 | c.1667A>C p.Q556P | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99861487; called by muse, mutect2, varscan2
- ERBB4 | c.835T>G p.F279V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99629535; called by muse, mutect2, varscan2
- FLNC | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs966097091, COSV100368490, COSV57952945; called by muse, mutect2, varscan2
- FMN2 | c.117C>A p.S39R | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as rs1004240278; called by mutect2, varscan2
- FSHR | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV100437719; called by muse, mutect2, varscan2
- GAD2 | c.404T>C p.F135S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99393765; called by muse, mutect2, varscan2
- GALNT10 | c.1799T>G p.F600C | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV51722100; called by muse, mutect2, varscan2
- GRM1 | c.2432A>C p.K811T | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99268087; called by muse, mutect2, varscan2
- HCFC2 | c.970G>A p.G324S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs144090047; called by muse, mutect2, varscan2
- HEXIM2 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100217957; called by muse, mutect2, varscan2
- IGF2BP3 | c.1204-2A>C p.X402_splice | Splice Site (SNP) | VAF 29/124 reads (23%) | catalogued as COSV99325657; called by muse, mutect2, varscan2
- IMPG1 | c.484A>C p.S162R | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs868757327, COSV100886554; called by muse, mutect2, varscan2
- IRF4 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs755460615, COSV66705603; called by muse, mutect2, varscan2
- KCNK18 | c.179A>C p.K60T | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100572111; called by muse, mutect2, varscan2
- KCNT2 | c.1464A>C p.E488D | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54071771, COSV54078801; called by muse, mutect2, varscan2
- KIFAP3 | c.2273G>T p.S758I | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV100847059; called by muse, mutect2, varscan2
- KMT2C | c.5618C>A p.T1873N | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100074860; called by muse, mutect2, varscan2
- KRT74 | c.865C>T p.H289Y | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs893259563, COSV99977640; called by muse, mutect2, varscan2
- LAYN | c.919C>T p.R307W (on ENST00000375615 / NM_001258390.1; = p.R299W on NM_178834.5) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs573383457, COSV100986258; called by muse, mutect2, varscan2
- LRP1B | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as rs1300495065, COSV101255023, COSV101259071, COSV67263835; called by muse, mutect2, varscan2
- MAGEC1 | c.1811A>T p.D604V | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.987); catalogued as COSV99596204; called by muse, mutect2, varscan2
- MCCC1 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs754187797, COSV99659970; called by muse, mutect2, varscan2
- MORC1 | c.2788A>G p.K930E | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs994306246, COSV99227186; called by muse, mutect2, varscan2
- MROH9 | c.232A>C p.S78R | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as COSV100882917; called by muse, mutect2, varscan2
- MUC16 | c.24304A>C p.T8102P | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.529); catalogued as COSV101200657; called by muse, mutect2, varscan2
- MYO15A | c.9401G>A p.R3134Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs373695303; called by muse, mutect2, varscan2
- NHS | c.4808C>T p.T1603M | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs367919114, COSV66275228; called by muse, mutect2, varscan2
- NTRK3 | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as rs761822626, COSV100447828, COSV58135762; called by muse, mutect2, varscan2
- OCA2 | c.92T>G p.L31R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.742); catalogued as COSV100668340; called by muse, mutect2, varscan2
- OR3A2 | c.10C>A p.Q4K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV101375068; called by muse, mutect2, varscan2
- OR4M1 | c.589T>G p.L197V | Missense Mutation (SNP) | VAF 27/273 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs757403933, COSV100271428; called by muse, mutect2, varscan2
- OR51G1 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.11); catalogued as COSV100429342; called by muse, mutect2, varscan2
- OR52D1 | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100495284; called by muse, mutect2, varscan2
- OR5L2 | c.524A>G p.N175S | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as rs1220544131, COSV101004376; called by muse, mutect2, varscan2
- OR6Y1 | c.547T>G p.F183V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV100225455; called by muse, mutect2
- OR7A17 | c.311T>G p.F104C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.267); catalogued as COSV100541660, COSV59413849, COSV59414424; called by muse, mutect2, varscan2
- OR8G1 | c.772A>T p.M258L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV100422568; called by muse, mutect2, varscan2
- OR8I2 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs568504554, COSV100136329, COSV56166446; called by muse, mutect2, varscan2
- OTOF | c.5566C>T p.R1856W (on ENST00000272371 / NM_194248.3; = p.R1089W on NM_004802.4) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs368155547, CM1513118; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH10 | c.946T>G p.L316V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV99994199; called by muse, mutect2, varscan2
- PCDHA4 | c.2267C>A p.P756Q | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV63543519, COSV63546245; called by muse, mutect2, varscan2
- PLEKHG7 | c.1600A>T p.R534* | Nonsense Mutation (SNP) | VAF 17/94 reads (18%) | catalogued as COSV100760158, COSV60821112; called by muse, mutect2, varscan2
- PLOD2 | c.1008A>C p.E336D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.92); catalogued as COSV99283098; called by muse, mutect2, varscan2
- PLXNA3 | c.1316A>C p.K439T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100860147; called by muse, mutect2, varscan2
- PRSS23 | c.409T>C p.F137L | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99722520; called by muse, mutect2, varscan2
- PTPRJ | c.3251T>G p.L1084R | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101395627; called by muse, mutect2, varscan2
- PTPRT | c.2185A>C p.T729P | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.958); catalogued as COSV100629328, COSV61984794, COSV61991253; called by muse, mutect2
- RAP1GDS1 | c.894A>C p.L298F (on ENST00000408927 / NM_001100427.2; = p.L299F on NM_021159.5) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as COSV99217214, COSV99217334; called by muse, mutect2, varscan2
- RTL9 | c.3019A>G p.T1007A | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as COSV101511761; called by muse, mutect2
- RXFP2 | c.774A>C p.Q258H | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1473566853, COSV53636515; called by muse, mutect2, varscan2
- RXRG | c.842T>G p.V281G | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100717733; called by mutect2, varscan2
- SDF4 | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.769); catalogued as rs113681668; called by muse, mutect2, varscan2
- SEMA6D | c.228A>C p.Q76H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV100317366; called by muse, mutect2, varscan2
- SETD1A | c.1385C>A p.P462Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as rs1001123633, COSV99353496; called by muse, mutect2
- SPEG | c.7865A>C p.K2622T | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as COSV100405211; called by muse, mutect2, varscan2
- ST8SIA1 | c.883T>C p.F295L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99683432; called by muse, mutect2, varscan2
- STK26 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as COSV100049173; called by muse, mutect2, varscan2
- TAOK1 | c.130T>A p.F44I | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV99914505; called by muse, mutect2, varscan2
- TBC1D31 | c.547A>G p.I183V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV54863825, COSV54868082; called by muse, mutect2, varscan2
- TLR3 | c.1302A>C p.E434D | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99711126; called by muse, mutect2, varscan2
- TMEM9 | c.75A>C p.E25D | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100947427; called by muse, mutect2, varscan2
- TRAK1 | c.988G>C p.E330Q (on ENST00000327628 / NM_001349247.2; = p.E272Q on NM_014965.5) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.214); catalogued as COSV100410205, COSV58259657; called by muse, mutect2, varscan2
- TTK | c.979T>A p.L327I | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100036494; called by muse, mutect2, varscan2
- TTN | c.6779T>G p.L2260R (on ENST00000591111; = p.L2214R on NM_003319.4) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | PolyPhen probably damaging (0.999); catalogued as COSV100623271; called by muse, mutect2, varscan2
- UBE2C | c.299C>G p.T100R | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54755069, COSV99708743; called by muse, mutect2, varscan2
- UVSSA | c.866T>C p.L289P | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV101104562; called by mutect2, varscan2
- VGLL2 | c.27A>C p.Q9H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.921); catalogued as COSV100409977; called by muse, mutect2, varscan2
- VRTN | c.1499T>G p.L500R | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99832371; called by muse, mutect2, varscan2
- WASF1 | c.788T>G p.L263R | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV100846937; called by muse, mutect2, varscan2
- ZEB2 | c.2963G>A p.R988H | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776367143, COSV100356568; called by muse, mutect2, varscan2
- ZFYVE9 | c.3043T>G p.L1015V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99820476; called by muse, mutect2, varscan2
- ZNF12 | c.1241G>A p.C414Y (on ENST00000405858 / NM_016265.4; = p.C376Y on NM_006956.3) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100703812; called by muse, mutect2
- ZNF347 | c.467T>C p.L156P | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.496); catalogued as COSV100498373; called by muse, mutect2, varscan2
- ZNF790 | c.257A>C p.K86T | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); catalogued as COSV63211927, COSV63212088; called by muse, mutect2, varscan2
- ZNF804A | c.3286A>C p.T1096P | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100169352; called by muse, mutect2, varscan2
- ZRANB1 | c.616A>C p.S206R | Missense Mutation (SNP) | VAF 46/77 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV100669296; called by muse, mutect2, varscan2
- ACACA | c.3302C>T p.T1101I | Missense Mutation (SNP) | VAF 108/309 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MAML1 | c.736_741del p.L246_N247del | In Frame Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel
- PRAMEF15 | c.421C>A p.P141T | Missense Mutation (SNP) | VAF 45/539 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); called by muse, mutect2
- RAD51C | c.145+4_145+7del | Splice Region (DEL) | VAF 22/62 reads (35%) | called by mutect2, pindel, varscan2
- CCDC54 | c.756T>G p.T252= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as rs1179679682, COSV53758328; called by muse, mutect2, varscan2
- CEMIP | c.3519C>T p.G1173= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs145572198; called by muse, varscan2
- CLCA4 | c.1074G>A p.K358= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV55367923; called by muse, mutect2, varscan2
- CNTN1 | c.1854T>G p.T618= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as rs1456731649, COSV100751754; called by muse, mutect2, varscan2
- CNTN1 | c.3021G>T p.L1007= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs1261768969, COSV100751074, COSV100751756; called by muse, mutect2, varscan2
- CNTN6 | c.795C>T p.D265= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as rs758805504, COSV63164423; called by muse, mutect2, varscan2
- COL6A3 | c.2931C>T p.N977= | Silent (SNP) | VAF 14/177 reads (8%) | catalogued as rs774059985, COSV55101094; called by muse, mutect2
- GAB4 | c.12G>A p.P4= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs1167981055, COSV101271915; called by muse, mutect2, varscan2
- GXYLT2 | c.1245A>G p.Q415= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV101274653; called by muse, mutect2, varscan2
- IGSF1 | c.2625C>T p.P875= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1334165967, COSV100812211; called by muse, mutect2, varscan2
- INPPL1 | c.2697G>A p.K899= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs1488198589, COSV99996484; called by muse, mutect2, varscan2
- IRF1 | c.975G>A p.P325= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs756898983, COSV55377546; called by muse, mutect2, varscan2
- ME1 | c.1023T>C p.V341= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs1221211724, COSV100866621; called by muse, mutect2, varscan2
- MED12L | c.4332T>G p.G1444= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99854139; called by muse, mutect2, varscan2
- MUC16 | c.210G>A p.S70= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs751083676, COSV101200658; called by muse, mutect2, varscan2
- MYH8 | c.3480T>G p.T1160= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV101238582; called by muse, mutect2, varscan2
- NOVA1 | c.1294T>C p.L432= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV57482791, COSV99946344; called by muse, mutect2, varscan2
- OR2F2 | c.94T>C p.L32= | Silent (SNP) | VAF 29/157 reads (18%) | catalogued as COSV101283826, COSV101283839, COSV68832894; called by muse, mutect2, varscan2
- OR6K3 | c.823T>C p.L275= (on ENST00000368146; = p.L259= on NM_001005327.2) | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs371617141, COSV63745754, COSV63746082; called by muse, mutect2, varscan2
- PCDHA6 | c.213C>T p.R71= | Silent (SNP) | VAF 38/161 reads (24%) | catalogued as COSV100972473; called by muse, varscan2
- PIK3CA | c.1764A>G p.K588= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs1174763085, COSV99841513; called by muse, mutect2
- SPIRE1 | c.2208C>T p.F736= (on ENST00000409402 / NM_001128626.2; = p.F722= on NM_020148.3) | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100563898; called by muse, mutect2, varscan2
- SPOCK3 | c.411C>T p.S137= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs773033592, COSV100693657; called by muse, mutect2, varscan2
- THSD7B | c.2830A>C p.R944= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV99755819; called by muse, mutect2, varscan2
- TMEM175 | c.1446C>T p.P482= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs758004779, COSV99298063; called by muse, varscan2
- WEE2 | c.645T>G p.V215= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as COSV101285214; called by muse, mutect2, varscan2
- ZMIZ1 | c.1965C>T p.H655= | Silent (SNP) | VAF 76/113 reads (67%) | catalogued as rs1001817793, COSV100566408; called by muse, mutect2, varscan2
- AGAP7P | n.1497G>A | RNA (SNP) | VAF 13/177 reads (7%) | catalogued as rs782493347; called by muse, mutect2, varscan2
- HNF4G | c.-23-3795A>C | Intron (SNP) | VAF 45/122 reads (37%) | catalogued as COSV62971987; called by muse, mutect2, varscan2
- MIR409 | n.31T>A | RNA (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- SSX9P | n.342T>G | RNA (SNP) | VAF 50/111 reads (45%) | called by muse, mutect2, varscan2
- ZBTB14 | c.-1C>T | 5'UTR (SNP) | VAF 3/33 reads (9%) | catalogued as rs1054981505, COSV100813487; called by muse, mutect2
- ZNF99 | c.*825T>G | 3'UTR (SNP) | VAF 7/50 reads (14%) | catalogued as COSV101233908; called by muse, mutect2, varscan2
